TCGA case TCGA-58-8391 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Thoraxklinik at University Hospital Heidelberg. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9ed5c6fe-24d2-4ee6-88ba-7319c9cfa05e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 57 years; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 57.8 years (21,102 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,167 days (5.9 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Gemcitabine; Days to treatment start: 42 days; Days to treatment end: 159 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 133 days; Days to treatment end: 180 days; Treatment dose: 50 Gy; Treatment outcome: Complete Response; Number of fractions: 7; Treatment anatomic sites: Regional Site.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 63.3 years (23,135 days); Days to diagnosis: 2,033 days (5.6 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Distant Site.
3. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 63.3 years (23,135 days); Days to diagnosis: 2,033 days (5.6 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Days to follow up: 1,342 days (3.7 years); Disease response: Tumor Free.
- Day 2,033 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 2,033 days (5.6 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 2,167 days (5.9 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Other clinical attributes
- FEV1/FVC before bronchodilator (%): 74; FEV1 before bronchodilator (% of reference): 75.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 30.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-58-8391-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-58-8391-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 88; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 3; Percent lymphocyte infiltration: 8.
  Slide TCGA-58-8391-01A-01-TS1: Section location: Top; Percent tumor cells: 92; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 5; Percent lymphocyte infiltration: 10.
- Sample TCGA-58-8391-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-58-8391-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 1.
  Slide TCGA-58-8391-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: Bronchial; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event surgery met: No.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis; New tumor event type: New Primary Tumor.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,167 days; disease-specific survival: no event (censored), 2,167 days; disease-free interval: event (new tumor event after initially disease-free), 2,033 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,033 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-58-8391-01A-11D-2322-01): tumor purity 0.62, ploidy 3.17, whole-genome doublings 1.
